Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88W, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88W-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME
BIRTHDATE:

PATIENT NBR:

PAGE #: 5
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old male with has long history of achalasia.
Operative Procedure/Tissue Submitted: Transhiatal esophagectomy, J-tube
placement. Cervical esophageal margin free; non-stapled margin. Wants to know
if there is malignancy.

PROCEDURE:

VERIFIED BY:

1. "Non-stapled margin, cervical esophageal margin." Received fresh in a small container is a 3.0 x 2.0 x 1.2 cm strip of mucosa. The mucosa is tan-grey and slightly granular with submucosal hemorrhages. The non-stapled end is shaved.
- 1A. Shaved margin.
- Frozen section control.
2. "Proximal stomach and esophagus."

Received in formalin in a large container is a 17.5 cm long segment of esophagus with a 6.2 x 3.2 x 1.5 cm portion of proximal stomach. The adventitia and red and ragged with a defect noted 2 cm away from the proximal margin. A friable grey-tan tissue is extending from the defect. The esophagus is dilated to internal circumference of 13.3 cm that narrows at the esophagogastric junction with an internal circumference of 2.8 cm. The mucosa of the esophagus is granular grey-white, thickened, somewhat rugated mucosa with areas of granular grey-white scaly tissue. It is remarkable for a 5.2 x 4.3 x 2.2 cm red-grey verrucoid tumors that is 0.1 cm away from the proximal margin. It is also located at the aforementioned perforation. The proximal margin is inked blue. Tumor is extremely friable. The tumor has a maximum depth of 0.2 cm and extends to the adventitia within the area of the perforation. Multiple possible lymph nodes are identified. They range up to 1.0 cm.

- 2A - 2C. Tumor to proximal margin.
- 2D and 2E. Tumor to deep and perforation.
- 2F - 2N. A strip from proximal to most distal with the proximal end inked blue.
- 2O - 2X. A second strip of esophagus from proximal esophagus to distal margin. Proximal end is inked blue.
- 2Y. Granular scaly esophageal mucosa.
- 2Z. Possible lymph nodes.
- Photographs have been taken.
3. "Cervical paraesophageal lymph nodes." Received in formalin in a small container is a 1.7 cm lymph node. Bisected.
4. "Cervical lymph node." Received in formalin in a small container is a 0.4 cm portion of yellow soft tissue.
5. "Gastrosplenic lymph node." Received in formalin in a small container is a 0.6 cm portion of grey-yellow soft tissue. Definite lymph nodes not identified.

ICD-O-3
Carcinoma, squamous cell 8670/3
Site ^{CSUE} Distal third esophagus C15.5
^{path}
Gastroesophageal junction C16.0
JW 11/12/13

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 6
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

FROZEN SECTION REPORT

1. Squamous hyperplasia. Negative for carcinoma.

I, _____ have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Squamous cell carcinoma.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 0/8

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: Yes.

TNM classification: T3 N0 Mx

PROCEDURE:

VERIFIED BY:

1. Cervical esophageal margin, intraoperative biopsy: Squamous hyperplasia, no invasive carcinoma.

2. Proximal stomach and esophagus, resection: Transmurally invasive well-differentiated squamous cell carcinoma extending to the deep (radial) margin of resection. Six lymph nodes negative for neoplasm. Squamous hyperplasia, chronic inflammation and lack of ganglion cells consistent with achalasia.

3. Cervical paraesophageal lymph nodes, excision: One lymph node negative for neoplasm.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 7
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

4. Cervical lymph node, excision: One lymph node negative for neoplasm.

5. Gastrosplenic lymph node, excision: Benign fibroadipose tissue.

I, _____ the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Criteria	10/21/13	No
Dual/Synchronous/Primary Noted		

Source: NCI Genomic Data Commons file 9c8e74a5-a645-4dcd-9902-6021117b5b6d (TCGA-L5-A88W.8BF174B0-88E5-4F9A-841C-12B43AC191B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).